Somatic mutation profile of tumor specimen TCGA-BR-4279-01A (aliquot TCGA-BR-4279-01A-01D-1126-08) from TCGA case TCGA-BR-4279, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 44.0 years (16,065 days).
Specimen TCGA-BR-4279-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d7dbc7c-1f47-4bea-9f0c-3276ee1757d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4279-11A (Solid Tissue Normal), aliquot TCGA-BR-4279-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa7451bf-bd2e-4bb3-ba92-c807020c8f56

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 18, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Splice Region 1, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, varscan2
- ACOT12 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs564306951, COSV56892647, COSV56894194; called by muse, mutect2, varscan2
- ADAMTS18 | c.1219T>G p.F407V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1567510967, COSV51404692; called by muse, mutect2, varscan2
- AK3 | c.683G>C p.*228Sext*20 | Nonstop Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV63346577; called by muse, mutect2, varscan2
- ANKRD10 | c.922G>C p.G308R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57443374; called by muse, mutect2, varscan2
- AP3M2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs777884964, COSV51527592; called by mutect2, varscan2
- B3GNT7 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55006252; called by muse, mutect2, varscan2
- BEST4 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV64733818; called by muse, mutect2, varscan2
- BRMS1L | c.361+2T>C p.X121_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV53762936; called by muse, mutect2
- BRWD1 | c.3668del p.S1223Lfs*3 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as COSV60894805; called by mutect2, pindel, varscan2
- CCDC60 | c.884-1G>T p.X295_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59542647; called by muse, mutect2, varscan2
- CDH1 | c.664A>G p.R222G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55730898; called by muse, mutect2, varscan2
- CDH1 | c.1936+1G>T p.X646_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV55730906, COSV55731485; called by muse, mutect2, varscan2
- CER1 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1563780346, COSV66603096; called by muse, mutect2, varscan2
- ENTPD4 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 52/235 reads (22%) | catalogued as rs368799155; called by muse, mutect2, varscan2
- GPSM1 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs112449667, COSV99395878; called by mutect2, varscan2
- HELZ2 | c.4097G>A p.C1366Y (on ENST00000467148 / NM_001037335.2; = p.C797Y on NM_033405.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71295742; called by muse, mutect2, varscan2
- HSD17B4 | c.1712A>G p.Q571R (on ENST00000414835 / NM_001199291.3; = p.Q546R on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56334963; called by muse, mutect2, varscan2
- KCNH6 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs778276731, COSV59002595; called by muse, mutect2, varscan2
- KIFC1 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65737475; called by muse, mutect2, varscan2
- MUC16 | c.2062T>C p.S688P | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV67459691; called by muse, mutect2, varscan2
- NEDD1 | c.1838A>T p.N613I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57142737; called by muse, mutect2, varscan2
- PCDHGA7 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV53929533; called by muse, mutect2, varscan2
- PDPN | c.448G>A p.V150I (on ENST00000621990; = p.V226I on NM_006474.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377220172; called by muse, mutect2, varscan2
- RIMS1 | c.4512A>G p.I1504M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs746893761, COSV53450685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RXFP1 | c.1069A>G p.N357D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs369234753; called by mutect2, varscan2
- SLC5A8 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs548387327, COSV73310518; called by mutect2, varscan2
- TMEM132B | c.2026C>T p.R676* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV54750796; called by muse, mutect2, varscan2
- TOP1MT | c.1218G>A p.T406= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as COSV61317283; called by muse, mutect2
- USH2A | c.4472A>T p.E1491V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56356631; called by muse, mutect2, varscan2
- ASH1L | c.818dup p.P274Afs*12 | Frame Shift Ins (INS) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- DST | c.8700del p.A2901Qfs*3 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- MON2 | c.3571_3572del p.V1191* | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.265C>A p.R89= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV54444085; called by muse, mutect2, varscan2
- BDP1 | c.639G>A p.S213= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1363533773, COSV62430694; called by muse, varscan2
- C8orf58 | c.165C>T p.V55= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs138371466; called by mutect2, varscan2
- CDC45 | c.804A>G p.T268= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV54244618; called by muse, mutect2, varscan2
- CDH8 | c.1935G>A p.R645= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100180371, COSV54878583; called by mutect2, varscan2
- COL7A1 | c.4368C>T p.G1456= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV60394128; called by muse, mutect2, varscan2
- DRD3 | c.540C>A p.V180= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV55680018; called by muse, mutect2, varscan2
- HSPA1L | c.693T>C p.G231= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1288581682, COSV65148991, COSV65149473; called by muse, mutect2, varscan2
- INPPL1 | c.2922C>A p.A974= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs200100388, COSV53353743; called by mutect2, varscan2
- KIF13B | c.2313A>G p.K771= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs187424275, COSV72879471; called by muse, mutect2, varscan2
- LPA | c.3489C>T p.P1163= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs758300066, COSV60300411; called by muse, mutect2, varscan2
- LRRK2 | c.6207T>G p.T2069= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54150012; called by muse, mutect2, varscan2
- MED26 | c.231G>A p.L77= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99659858; called by muse, mutect2, varscan2
- OR4K17 | c.588G>A p.Q196= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs775922448, COSV59647857; called by muse, mutect2, varscan2
- SPPL2C | c.1149G>T p.L383= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV61292225; called by muse, mutect2, varscan2
- SYNE1 | c.17097C>T p.P5699= (on ENST00000367255 / NM_182961.4; = p.P5628= on NM_033071.3) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs769890058, COSV54957117; called by mutect2, varscan2
- TRIM25 | c.783G>A p.R261= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs766353810, COSV57543856; called by muse, mutect2, varscan2
- USP29 | c.1782C>T p.P594= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs35663514, COSV99518439; called by muse, mutect2, varscan2
- DCHS2 | n.2403C>T | RNA (SNP) | VAF 14/68 reads (21%) | catalogued as rs1186747227, COSV59723572; called by muse, mutect2, varscan2
- FAS | c.*279T>A | 3'UTR (SNP) | VAF 17/91 reads (19%) | catalogued as COSV58238505; called by muse, mutect2, varscan2
